FM case AD16749 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Squamous Cell Neoplasms; Primary site: Esophagus.
https://portal.gdc.cancer.gov/cases/44c8b3cd-8951-46ea-9c7f-62ee02b65067

Male, 50.8 years: Squamous cell carcinoma, NOS (ICD-O-3 8070/3) of the esophagus; metastasis biopsied or resected from the larynx. Tumor nuclei on the sequenced sample's slide: 20% (pathologist estimate recorded by GDC). Sample type: Metastatic.
